Somatic mutation profile of tumor specimen TCGA-CH-5766-01A (aliquot TCGA-CH-5766-01A-11D-1576-08) from TCGA case TCGA-CH-5766, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.8 years (20,392 days).
Specimen TCGA-CH-5766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f62b29e0-104c-45f7-8c3d-8429408ef767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5766-11A (Solid Tissue Normal), aliquot TCGA-CH-5766-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59543fff-17cf-4a83-b95b-4f033d3fd6da

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs775100778, COSV52232803; called by muse, mutect2, varscan2
- ANKRD12 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs1567933551, COSV50854069; called by muse, mutect2
- CCDC105 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1363224809, COSV52963869; called by muse, mutect2, varscan2
- CENPI | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs928336044, COSV54505958, COSV54506416, COSV54506899; called by muse, mutect2, varscan2
- CENPP | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65042286; called by muse, mutect2, varscan2
- CSMD2 | c.4705C>T p.R1569W | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53967050; called by muse, mutect2
- DOP1B | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV67696792; called by muse, mutect2, varscan2
- FRMD7 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV53749368; called by muse, mutect2, varscan2
- MOCOS | c.2228A>T p.N743I | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347254; called by muse, mutect2, varscan2
- MPP2 | c.1444A>G p.T482A (on ENST00000461854 / NM_001278372.2; = p.T458A on NM_005374.5) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52240915; called by muse, mutect2
- NFYC | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV58130513; called by muse, mutect2, varscan2
- OTUD4 | c.3123G>T p.Q1041H (on ENST00000447906 / NM_001366057.1; = p.Q976H on NM_001102653.1) | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV71382366; called by muse, mutect2, varscan2
- PSMD6 | c.1105A>C p.T369P | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV55761605; called by muse, mutect2, varscan2
- SCN7A | c.4199A>G p.Y1400C | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772074342, COSV69275152; called by muse, mutect2, varscan2
- SYNE1 | c.20075C>T p.S6692F (on ENST00000367255 / NM_182961.4; = p.S6621F on NM_033071.3) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as COSV55121997; called by muse, mutect2
- TMEM167B | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs749080465, COSV57808709; called by muse, mutect2, varscan2
- TTN | c.92667A>T p.Q30889H (on ENST00000591111; = p.Q23465H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | PolyPhen possibly damaging (0.655); catalogued as COSV60392074; called by muse, mutect2, varscan2
- TTN | c.12097G>C p.V4033L (on ENST00000591111; = p.V3987L on NM_003319.4) | Missense Mutation (SNP) | VAF 16/159 reads (10%) | catalogued as COSV60392111; called by muse, mutect2, varscan2
- HEXB | c.1425_1427dup p.K476dup | In Frame Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- DLEC1 | c.1800T>C p.G600= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV57307718; called by muse, mutect2, varscan2
- EPHB1 | c.1998G>C p.L666= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV67673221; called by muse, mutect2
- HDAC11 | c.447C>T p.G149= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs766875680, COSV55472687; called by muse, varscan2
- KCNT1 | c.906G>A p.T302= (on ENST00000488444; = p.T321= on NM_020822.3) | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs760300415, COSV53712445; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF26B | c.2952C>A p.S984= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100831554, COSV63647880; called by muse, mutect2
- LSP1 | c.375C>T p.Y125= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs577198149, COSV61138036; called by muse, mutect2, varscan2
- SLC4A9 | c.1692C>T p.Y564= (on ENST00000507527 / NM_001258428.2; = p.Y540= on NM_031467.3) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs369172069; called by muse, mutect2, varscan2
- TSPAN9 | c.642C>T p.I214= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1240554268, COSV50728627; called by muse, mutect2, varscan2
- ZAN | c.1488C>A p.V496= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV61817896; called by muse, mutect2, varscan2
